Somatic mutation profile of tumor specimen 0DJ8KQ from CCDI case PBBWJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,324 days).
Specimen 0DJ8KQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66a622e-1650-4203-bd76-0486e8e77009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ8JL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78b0593b-b1a4-487a-99d1-a5dfb21f737d

The open-access MAF lists 7 somatic variants for this specimen: 1 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 3'UTR 2, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ROS1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs768790336, COSV63856637; called by muse, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as rs1262556378; called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 42/410 reads (10%) | called by muse, varscan2
- PCID2 | c.37-96G>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV55814251; called by muse, varscan2
- UQCRHL | c.-74C>G | 5'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, varscan2
